Somatic mutation profile of tumor specimen TCGA-AA-A00Z-01A (aliquot TCGA-AA-A00Z-01A-01D-A17O-10) from TCGA case TCGA-AA-A00Z, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 70.8 years (25,872 days).
Specimen TCGA-AA-A00Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8aeb0850-46aa-49c1-8e7c-009b6efbae0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A00Z-10A (Blood Derived Normal), aliquot TCGA-AA-A00Z-10A-01W-A005-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81eefa7d-97a0-4e67-a24d-e558facfe5c2

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SOX9 | c.491A>C p.Q164P | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as rs1567910689, COSV99818669; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS10 | c.3187G>A p.G1063R | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs782617003, COSV99547503; called by muse, mutect2
- BSN | c.2708C>T p.T903M | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs773534381, COSV56526696; called by muse, mutect2, varscan2
- MAP3K1 | c.3601G>T p.A1201S | Missense Mutation (SNP) | VAF 84/118 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV101267143; called by muse, mutect2, varscan2
- PACSIN2 | c.145G>C p.A49P | Missense Mutation (SNP) | VAF 65/206 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99606776; called by muse, mutect2, varscan2
- PCDHA4 | c.1985C>T p.T662M | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.946); catalogued as COSV63539559; called by muse, mutect2, varscan2
- RXFP1 | c.2219A>G p.Y740C | Missense Mutation (SNP) | VAF 73/264 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.161); catalogued as COSV100314285; called by muse, mutect2, varscan2
- SALL3 | c.3865C>T p.R1289W | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs780459845, COSV101610063; called by muse, mutect2, varscan2
- ZXDA | c.1426G>C p.D476H | Missense Mutation (SNP) | VAF 36/39 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100699483, COSV62387723; called by muse, mutect2, varscan2
- TAS2R40 | c.276_277del p.I95Pfs*27 | Frame Shift Del (DEL) | VAF 73/259 reads (28%) | called by mutect2, pindel, varscan2
- PLCE1 | c.4881A>C p.I1627= | Silent (SNP) | VAF 75/292 reads (26%) | catalogued as COSV99597509; called by muse, mutect2, varscan2
- SPTA1 | c.3195C>T p.R1065= | Silent (SNP) | VAF 116/359 reads (32%) | catalogued as COSV100935668; called by muse, mutect2, varscan2
